TCGA case TCGA-24-1105 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7e01f23a-0b0e-46a2-9f30-c3a9d2c779d2

Demographics
Sex at birth: female; Race: white; Age at index: 36 years; Vital status: Dead; Days to death: 1,442 days (3.9 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 36.1 years (13,187 days); Year of diagnosis: 2001; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 178 days; Number of cycles: 6; Treatment dose: 3,410 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 178 days; Number of cycles: 6; Treatment dose: 1,400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 486 days (1.3 years); Days to treatment end: 584 days (1.6 years); Number of cycles: 6; Treatment dose: 3,360 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 486 days (1.3 years); Days to treatment end: 584 days (1.6 years); Number of cycles: 6; Treatment dose: 1,725 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 724 days (2.0 years); Days to treatment end: 860 days (2.4 years); Number of cycles: 6; Treatment dose: 48 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Recurrent Disease; Days to treatment start: 724 days (2.0 years); Days to treatment end: 860 days (2.4 years); Number of cycles: 6; Treatment dose: 486 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,004 days (2.7 years); Days to treatment end: 1,116 days (3.1 years); Number of cycles: 4; Treatment dose: 19,320 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,004 days (2.7 years); Days to treatment end: 1,116 days (3.1 years); Number of cycles: 4; Treatment dose: 258 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,130 days (3.1 years); Days to treatment end: 1,200 days (3.3 years); Number of cycles: 4; Treatment dose: 2,275 mg; Route of administration: Intraperitoneal.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,228 days (3.4 years); Days to treatment end: 1,298 days (3.6 years); Treatment dose: 2,001 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 1,228 days (3.4 years); Days to treatment end: 1,298 days (3.6 years); Treatment dose: 4,500 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 1,263 days (3.5 years); Days to treatment end: 1,285 days (3.5 years); Treatment dose: 7,000 cGy; Number of fractions: 28; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 1,313 days (3.6 years); Days to treatment end: 1,340 days (3.7 years); Number of cycles: 2; Treatment dose: 975 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 1,368 days (3.7 years); Days to treatment end: 1,375 days (3.8 years); Number of cycles: 1; Treatment dose: 92 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 1,368 days (3.7 years); Days to treatment end: 1,375 days (3.8 years); Number of cycles: 1; Treatment dose: 1,826 mg; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 37.4 years (13,657 days); Days to diagnosis: 470 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (2 entries)
- Day 470 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 470 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,442 days (3.9 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1105-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 1; Shortest dimension: 0.8.
  Slide TCGA-24-1105-01A-01-BS1: Section location: Bottom; Percent tumor nuclei: 90; Percent necrosis: 5.
  Slide TCGA-24-1105-01A-01-TS1: Section location: Top; Percent tumor nuclei: 90; Percent necrosis: 1.
- Sample TCGA-24-1105-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 3: Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Cytoxan; Therapy regimen: Progression.
- Drug treatment 4, Route of administrations: Route of administration: PO.
- Drug treatment 5: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 7: Pharmaceutical therapy drug name: Navelbine.
- Drug treatment 8: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 9: Pharmaceutical therapy drug name: Gemzar.
- Drug treatment 10: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 11: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 12, Route of administrations: Route of administration: IP.
- Radiation treatment: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Progression, Recurrence.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-24-1105-01): tumor purity 0.75, ploidy 3.51, whole-genome doublings 1 (call status: legacy_call).
